CCDI case PBCHLM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Granular Cell Tumors and Alveolar Soft Part Sarcomas; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/7ca07389-c860-4a72-b813-fc6fb2b12f27

Demographics
Sex at birth: female; Race: black or african american.

Diagnoses (1)
1. Alveolar rhabdomyosarcoma: ICD-O-3 morphology code: 8920/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of trunk, NOS; Age at diagnosis: 12.0 years (4,379 days).

Biospecimens (3 samples)
- Sample 0DS4L9: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DS4LB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DS4MM: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
